Somatic mutation profile of tumor specimen TCGA-76-4929-01A (aliquot TCGA-76-4929-01A-01D-1486-08) from TCGA case TCGA-76-4929, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,831 days).
Specimen TCGA-76-4929-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7509dfe-0abb-4aea-81c9-931e3f89656f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4929-10A (Blood Derived Normal), aliquot TCGA-76-4929-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da144c59-a31d-454f-9285-4f0cf3ed9ab6

The open-access MAF lists 68 somatic variants for this specimen: 43 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 24, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.2278C>T p.R760* (on ENST00000400246; = p.R829* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 90/127 reads (71%) | catalogued as rs1569067939, COSV56703206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 33/60 reads (55%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767328513, COSV52681003, COSV52850900, COSV53527150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAP1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50137979; called by muse, mutect2, varscan2
- ALS2 | c.2129G>C p.S710T | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.42); catalogued as COSV51889390, COSV51890306; called by muse, mutect2, varscan2
- ARHGAP6 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57298886; called by muse, mutect2
- CDH18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759064016, COSV56914916, COSV56935577; called by muse, mutect2, varscan2
- CDH4 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV64663127; called by muse, mutect2, varscan2
- CDKL5 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs753899592, COSV66112176; called by muse, mutect2, varscan2
- CLIP2 | c.2345G>A p.S782N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1554313019, COSV56281935; called by muse, mutect2, varscan2
- DCK | c.378T>G p.F126L | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV54379105; called by muse, mutect2, varscan2
- FGG | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs1171344473, COSV60195944; called by muse, mutect2, varscan2
- FKBPL | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 255/338 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100913568, COSV64322683; called by muse, mutect2, varscan2
- GAB4 | c.937+1G>A p.X313_splice | Splice Site (SNP) | VAF 114/151 reads (75%) | catalogued as rs769082245, COSV68754416; called by muse, mutect2, varscan2
- GABRB2 | c.1358G>A p.R453Q (on ENST00000274547; = p.R415Q on NM_000813.3) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs371728438; called by muse, mutect2, varscan2
- GRIPAP1 | c.2362C>T p.L788F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54414960; called by muse, mutect2, varscan2
- HADHA | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460602961, COSV66108040; called by muse, mutect2, varscan2
- KDM7A | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369398521; called by muse, mutect2, varscan2
- LRFN5 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 85/116 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53265980; called by muse, mutect2, varscan2
- MAGEA4 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 140/510 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1225342823, COSV52341486; called by muse, mutect2, varscan2
- MGAM | c.4529G>A p.R1510H | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760340491, COSV72075067; called by muse, mutect2, varscan2
- MOAP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 143/182 reads (79%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV52092948; called by muse, mutect2, varscan2
- MYO1B | c.1352A>T p.N451I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV58434114; called by muse, mutect2, varscan2
- NANP | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV59160238, COSV59160375; called by muse, mutect2, varscan2
- NEBL | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV65804409; called by muse, mutect2
- NEFL | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV55336934, COSV55337619; called by muse, mutect2, varscan2
- NTSR1 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.342); catalogued as COSV100980657, COSV65139045; called by muse, mutect2, varscan2
- NUDT2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV60678739; called by muse, mutect2, varscan2
- PABPC4 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.411); catalogued as rs139185037; called by muse, mutect2, varscan2
- PHOSPHO2 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV55868350; called by muse, mutect2, varscan2
- PIK3C2G | c.2093T>C p.I698T (on ENST00000676171; = p.I657T on NM_004570.5) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs998650200, COSV56818528; called by muse, mutect2, varscan2
- PKHD1 | c.3752C>A p.T1251N | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61885504; called by muse, mutect2, varscan2
- PLEKHG4B | c.3484G>A p.V1162I (on ENST00000283426; = p.V1518I on NM_052909.5) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs114040866, COSV52044468; called by muse, mutect2, varscan2
- PTPN3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374370776; called by muse, mutect2, varscan2
- RBP3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 77/102 reads (75%) | SIFT tolerated (0.87); PolyPhen benign (0.313); catalogued as rs782814427; called by muse, mutect2, varscan2
- RGS3 | c.1085G>A p.R362Q (on ENST00000350696 / NM_001282923.2; = p.R250Q on NM_017790.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58282770; called by muse, mutect2
- RGS9 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as COSV52227115; called by muse, mutect2
- TNFRSF4 | c.765G>A p.G255= | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as COSV64879174; called by muse, mutect2, varscan2
- WDR81 | c.3238C>T p.P1080S (on ENST00000409644 / NM_001163809.2; = p.P29S on NM_152348.4) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs753798569, COSV100488743; called by muse, mutect2, varscan2
- AKAP9 | c.8171del p.A2724Vfs*22 (on ENST00000359028; = p.A2700Vfs*22 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/205 reads (17%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.541del p.V181Ffs*26 | Frame Shift Del (DEL) | VAF 47/91 reads (52%) | called by mutect2, pindel, varscan2
- RBBP6 | c.3479_3480del p.F1160* | Frame Shift Del (DEL) | VAF 48/125 reads (38%) | called by mutect2, pindel, varscan2
- SLU7 | c.170+2del p.X57_splice | Splice Site (DEL) | VAF 35/146 reads (24%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.12G>A p.S4= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs371504666; called by muse, mutect2, varscan2
- ADO | c.93C>T p.S31= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs1475696093, COSV65677615, COSV65678074; called by muse, mutect2, varscan2
- ALG3 | c.711C>T p.I237= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56612536; called by muse, mutect2
- ANXA3 | c.327C>T p.N109= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as rs144437584; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.954C>T p.C318= | Silent (SNP) | VAF 153/281 reads (54%) | catalogued as COSV63438407; called by muse, mutect2, varscan2
- BASP1 | c.45C>T p.N15= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV59471923; called by muse, mutect2, varscan2
- CASQ1 | c.327A>T p.V109= | Silent (SNP) | VAF 115/302 reads (38%) | catalogued as COSV63624328; called by muse, mutect2, varscan2
- CLEC3A | c.507C>T p.N169= (on ENST00000651443; = p.N160= on NM_005752.6) | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs371337987, COSV104409488; called by muse, mutect2, varscan2
- FMNL1 | c.2163C>T p.T721= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV58957842; called by muse, mutect2, varscan2
- GYG2 | c.1458G>A p.K486= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV58550828; called by muse, mutect2, varscan2
- ICAM5 | c.2016C>A p.T672= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV55748117; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1302A>G p.L434= | Silent (SNP) | VAF 62/252 reads (25%) | catalogued as COSV56278158; called by muse, mutect2, varscan2
- INSL6 | c.144C>T p.A48= | Silent (SNP) | VAF 65/94 reads (69%) | catalogued as COSV67563154; called by muse, mutect2, varscan2
- IRX5 | c.1137C>T p.A379= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV58059417; called by muse, mutect2, varscan2
- KRT13 | c.414C>T p.D138= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as COSV55840558; called by muse, mutect2, varscan2
- KSR2 | c.2196G>A p.P732= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs140960062, COSV56677543; called by muse, mutect2, varscan2
- LHX9 | c.135C>T p.A45= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV61329906; called by muse, mutect2, varscan2
- MXRA5 | c.6990C>T p.V2330= | Silent (SNP) | VAF 124/459 reads (27%) | catalogued as rs369770483, COSV54241763; called by muse, mutect2, varscan2
- NAA35 | c.1938T>C p.Y646= | Silent (SNP) | VAF 137/307 reads (45%) | catalogued as rs764827218, COSV64485531; called by muse, mutect2, varscan2
- NOX1 | c.408C>T p.S136= | Silent (SNP) | VAF 181/680 reads (27%) | catalogued as COSV54195591, COSV99471590; called by muse, mutect2, varscan2
- PDGFRA | c.633A>G p.T211= | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as rs1370965730, COSV57270671; called by muse, mutect2
- PFAS | c.3231G>A p.R1077= | Silent (SNP) | VAF 93/215 reads (43%) | catalogued as COSV58981752; called by muse, mutect2, varscan2
- SLC11A1 | c.816C>T p.A272= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV51917219; called by muse, mutect2, varscan2
- TNFSF18 | c.574C>T p.L192= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as rs545086841, COSV53441060; called by muse, mutect2, varscan2
- NRXN1 | c.3719-1398G>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100640178; called by muse, mutect2, varscan2
